Somatic mutation profile of tumor specimen C3L-02119-06 (aliquot CPT0114340009) from CPTAC case C3L-02119, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.3 years (26,423 days).
Specimen C3L-02119-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c10bce2c-dd95-48e6-98f4-d17b0bdbd25b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02119-31 (Blood Derived Normal), aliquot CPT0116070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3f89922-f91a-4593-a620-012385f03ca0

The open-access MAF lists 120 somatic variants for this specimen: 95 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Frame Shift Del 13, Nonsense Mutation 11, Frame Shift Ins 2, Splice Site 2, 3'UTR 2, In Frame Del 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 21/158 reads (13%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.204C>A p.Y68* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); catalogued as CM110140, COSV64297713; called by muse, mutect2, varscan2
- TRIOBP | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 146/423 reads (35%) | catalogued as rs118204026, CM067723, COSV60376201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.721); catalogued as rs1191122727, COSV51971644; called by muse, mutect2, varscan2
- ADAMTS12 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 35/239 reads (15%) | catalogued as COSV61257453; called by muse, mutect2, varscan2
- AGO1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV100940935, COSV104427821; called by muse, mutect2
- ARID1A | c.3612del p.M1205* | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | catalogued as COSV61378853; called by mutect2, pindel, varscan2
- ARID1A | c.3977dup p.Q1327Afs*11 | Frame Shift Ins (INS) | VAF 66/322 reads (20%) | catalogued as COSV61376881; called by mutect2, pindel, varscan2
- ASAH1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 50/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048239757, COSV50502596; called by muse, mutect2
- ATXN7L2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.493); catalogued as rs572464653, COSV63992482; called by muse, mutect2, varscan2
- BEST4 | c.1312del p.R438Afs*82 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as rs755252994; called by mutect2, pindel, varscan2
- CCDC40 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 193/632 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs780647441, COSV53904438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.1315A>G p.K439E | Missense Mutation (SNP) | VAF 20/594 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99270481; called by muse, mutect2
- CRYBB3 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs375467933; called by muse, mutect2, varscan2
- DCAF5 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1463334506; called by muse, mutect2, varscan2
- DMXL1 | c.7615C>T p.R2539* | Nonsense Mutation (SNP) | VAF 136/412 reads (33%) | catalogued as COSV60708259; called by muse, mutect2, varscan2
- FGFBP3 | c.505C>G p.R169G | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs778883939; called by muse, mutect2, varscan2
- FLG | c.6991G>T p.G2331* | Nonsense Mutation (SNP) | VAF 269/1118 reads (24%) | catalogued as COSV64240605, COSV64247378; called by muse, mutect2, varscan2
- GRIN3A | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701329; called by muse, mutect2, varscan2
- GRK3 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.671); catalogued as rs755184733, COSV60794025; called by muse, mutect2, varscan2
- HCN1 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs141383188; called by muse, mutect2, varscan2
- ITPR3 | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs996981807; called by muse, mutect2, varscan2
- LGR6 | c.430C>T p.R144C (on ENST00000367278 / NM_001017403.1; = p.R92C on NM_021636.3) | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775637496, COSV99708073; called by muse, mutect2, varscan2
- MAGED1 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs374985036, COSV58515031; called by muse, mutect2, varscan2
- MTDH | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); catalogued as rs564170062; called by muse, mutect2, varscan2
- MYO18A | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.639); catalogued as rs375653114; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 33/156 reads (21%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NIPBL | c.7744C>T p.R2582* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV56940767; called by muse, mutect2, varscan2
- PIBF1 | c.1978_1981del p.E660Sfs*13 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs767868497; called by mutect2, pindel, varscan2
- PIK3R5 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 72/228 reads (32%) | catalogued as COSV99353100; called by muse, mutect2, varscan2
- PLCG1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs769294921; called by muse, mutect2
- PLG | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1472238075, COSV51983159; called by muse, mutect2, varscan2
- PRAMEF10 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1042088707; called by mutect2, varscan2
- PRKDC | c.6331C>T p.P2111S | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs777504270; called by muse, mutect2, varscan2
- PRMT2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170385214; called by muse, mutect2, varscan2
- RAG1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs763843831, COSV55023805; called by muse, mutect2, varscan2
- RIMBP2 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs751917288, COSV55477600; called by muse, mutect2, varscan2
- RIPOR2 | c.3169G>C p.G1057R | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52422361; called by muse, mutect2, varscan2
- RNFT1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs147639974, COSV59869529; called by muse, mutect2, varscan2
- SCN10A | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs148851890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGSM2 | c.2435C>T p.T812M (on ENST00000426855 / NM_001098509.2; = p.T857M on NM_014853.3) | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs375217455; called by muse, mutect2, varscan2
- SHPRH | c.4955G>T p.S1652I (on ENST00000275233 / NM_001042683.3; = p.S1656I on NM_173082.3) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV51604278; called by muse, mutect2, varscan2
- SLC22A18AS | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 93/315 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs76505120; called by muse, mutect2, varscan2
- SLC6A18 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs149805201; called by muse, mutect2
- SRGAP3 | c.2459G>A p.S820N | Missense Mutation (SNP) | VAF 35/571 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as rs748487712, COSV100841506; called by muse, mutect2
- ST14 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as rs746320143; called by muse, mutect2
- TANC1 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs769851661; called by muse, varscan2
- TLCD3A | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 30/454 reads (7%) | catalogued as rs747021307; called by muse, mutect2
- TMEM184A | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.378); catalogued as rs746902903; called by muse, mutect2, varscan2
- TRABD | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs200288166; called by muse, mutect2, varscan2
- TRERF1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV61676876; called by muse, mutect2, varscan2
- TRPM5 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs538607350; called by muse, mutect2, varscan2
- ZNF106 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 87/303 reads (29%) | catalogued as rs1162719676, COSV55515471; called by muse, mutect2, varscan2
- ARHGEF11 | c.4072G>A p.G1358R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2A | c.5444C>T p.A1815V | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH13 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- CEP63 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2
- CMTR2 | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- COL16A1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- COL17A1 | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC7 | c.1106del p.N369Mfs*6 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel
- GGA2 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HEPH | c.3321G>T p.M1107I (on ENST00000343002; = p.M840I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/472 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMJD1C | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); called by muse, mutect2
- KCNH8 | c.1867C>A p.Q623K | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KIAA0825 | c.1876del p.E626Kfs*29 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- MEGF8 | c.5857del p.R1953Afs*90 (on ENST00000251268 / NM_001271938.2; = p.R1886Afs*90 on NM_001410.3) | Frame Shift Del (DEL) | VAF 70/398 reads (18%) | called by mutect2, pindel, varscan2
- MICAL2 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2
- MICU1 | c.1071G>T p.K357N (on ENST00000361114 / NM_001195518.2; = p.K363N on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, varscan2
- NAA35 | c.2081T>G p.M694R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- NR2C2 | c.1762A>G p.N588D (on ENST00000393102; = p.N607D on NM_003298.5) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- NUDC | c.826-1G>A p.X276_splice | Splice Site (SNP) | VAF 34/642 reads (5%) | called by muse, mutect2
- NUP155 | c.3166G>T p.A1056S (on ENST00000231498 / NM_153485.3; = p.A997S on NM_004298.4) | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OMD | c.32T>C p.F11S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by mutect2, varscan2
- OR2G6 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 158/300 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUB1 | c.58+1G>C p.X20_splice | Splice Site (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- PAN3 | c.2501A>G p.H834R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PER1 | c.2280del p.S761Afs*4 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- PIK3CA | c.1380_1388del p.V461_G463del | In Frame Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- PLEKHG6 | c.1850del p.P617Lfs*38 | Frame Shift Del (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- PTEN | c.924_925del p.A309Rfs*2 | Frame Shift Del (DEL) | VAF 52/232 reads (22%) | called by mutect2, pindel, varscan2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- RNF38 | c.1492C>G p.R498G | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- SETBP1 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMARCA5 | c.519G>C p.S173= | Splice Region (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- SOX1 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2
- TBX4 | c.632del p.N211Tfs*17 | Frame Shift Del (DEL) | VAF 88/552 reads (16%) | called by mutect2, pindel, varscan2
- TMTC1 | c.2078_2079del p.Y693Lfs*44 (on ENST00000539277 / NM_001193451.2; = p.Y585Lfs*44 on NM_175861.3) | Frame Shift Del (DEL) | VAF 67/270 reads (25%) | called by mutect2, pindel, varscan2
- TP63 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- TRIM23 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRRAP | c.5368G>A p.G1790R (on ENST00000359863 / NM_001244580.1; = p.G1772R on NM_003496.3) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- ZKSCAN8 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ZNF703 | c.52_66del p.S18_G22del | In Frame Del (DEL) | VAF 152/448 reads (34%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.79T>C p.W27R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACP6 | c.318C>T p.Y106= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as rs782815891, COSV65078248; called by muse, mutect2, varscan2
- BCL9L | c.564C>G p.A188= | Silent (SNP) | VAF 46/182 reads (25%) | called by muse, mutect2, varscan2
- FBXL8 | c.993C>T p.R331= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV50457215; called by muse, mutect2
- GJC2 | c.1209C>A p.V403= | Silent (SNP) | VAF 103/413 reads (25%) | catalogued as COSV100812972; called by muse, mutect2, varscan2
- KCNJ6 | c.337T>C p.L113= | Silent (SNP) | VAF 46/300 reads (15%) | catalogued as COSV55711533; called by muse, mutect2, varscan2
- LAMB3 | c.1128C>T p.C376= | Silent (SNP) | VAF 37/762 reads (5%) | called by muse, mutect2
- LRRC9 | c.2610G>A p.T870= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs1172965752; called by muse, mutect2, varscan2
- MAGEA12 | c.12G>A p.E4= | Silent (SNP) | VAF 67/233 reads (29%) | catalogued as COSV63294606; called by muse, mutect2, varscan2
- MAGEL2 | c.1242G>A p.P414= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1482484525; called by muse, mutect2, varscan2
- METTL27 | c.549C>A p.T183= | Silent (SNP) | VAF 73/555 reads (13%) | called by muse, mutect2, varscan2
- NTSR2 | c.222C>T p.S74= | Silent (SNP) | VAF 126/336 reads (38%) | catalogued as rs747359813; called by muse, varscan2
- PCDHGA12 | c.525C>T p.N175= | Silent (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- PDZD4 | c.1527C>A p.P509= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- PKN3 | c.2406C>T p.L802= | Silent (SNP) | VAF 129/388 reads (33%) | catalogued as rs547767121; called by muse, mutect2, varscan2
- RBCK1 | c.204C>T p.T68= (on ENST00000356286 / NM_031229.4; = p.T26= on NM_006462.6) | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as rs189407509, COSV100675848; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCARF1 | c.441G>T p.V147= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1322118147; called by muse, mutect2, varscan2
- STAT2 | c.834G>A p.E278= | Silent (SNP) | VAF 62/233 reads (27%) | called by muse, mutect2, varscan2
- TAOK2 | c.1845G>A p.R615= | Silent (SNP) | VAF 14/409 reads (3%) | called by muse, mutect2
- VPS26B | c.768G>A p.T256= | Silent (SNP) | VAF 28/196 reads (14%) | catalogued as rs897983802; called by muse, mutect2, varscan2
- WIZ | c.1863G>A p.E621= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1364766940, COSV99653292; called by muse, varscan2
- ZNF749 | c.1218C>G p.G406= | Silent (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- ADM2 | c.*266G>A | 3'UTR (SNP) | VAF 49/184 reads (27%) | catalogued as rs897029059; called by muse, mutect2, varscan2
- PATJ | c.*3C>T | 3'UTR (SNP) | VAF 50/148 reads (34%) | catalogued as rs759207432; called by muse, mutect2, varscan2
- TBL2 | c.130+1754C>T | Intron (SNP) | VAF 42/226 reads (19%) | called by muse, mutect2, varscan2
- ZNF185 | c.1209-3453G>A | Intron (SNP) | VAF 14/198 reads (7%) | catalogued as rs1556890033; called by muse, mutect2
